Gene-level copy-number profile of tumor specimen TCGA-2G-AAEU-01A from TCGA case TCGA-2G-AAEU, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 34.7 years (12,672 days).
Specimen TCGA-2G-AAEU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2f2a2a1b-3a54-4ef3-8e00-5f5e1fd114ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAEU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/17ef014e-9dcf-48b9-87db-1e361ce47337

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 963; copy number 2: 20,614; copy number 3: 26,878; copy number 4: 8,581; copy number 5: 388; copy number 6: 651; copy number 7: 831.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 831 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 831 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 451. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
